TCGA case TCGA-EL-A3D6 — Thyroid Carcinoma (TCGA-THCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Thyroid gland; Tissue source site: MD Anderson. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/2106f0cd-cb3c-4568-bdc5-197ee11f2337

Demographics
Sex at birth: female; Race: white; Ethnicity: hispanic or latino; Country of residence at enrollment: United States; Age at index: 51 years; Vital status: Alive.

Diagnoses (1)
1. Papillary adenocarcinoma, NOS: ICD-O-3 morphology code: 8260/3; ICD-10 code: C73; Tissue or organ of origin: Thyroid gland; Site of resection or biopsy: Thyroid gland; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 51.0 years (18,640 days); Year of diagnosis: 1999; AJCC staging edition: 5th; AJCC pathologic T: T3; AJCC pathologic N: N1b; AJCC pathologic M: M0; AJCC pathologic stage: Stage III; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R1; Days to last follow up: 3,296 days (9.0 years); Tumor focality: Unifocal.
   Pathology details: Consistent pathology review: Yes; Extrathyroid extension: Minimal (T3); Lymph nodes positive: 1; Lymph nodes tested: 5; Measurement unit: Centimeters; Tumor depth measurement: 3.2; Tumor length measurement: 6; Tumor width measurement: 4.7.
   Treatment given: Treatment type: Radiation, Systemic; Days to treatment start: 86 days; Treatment dose: 100 mCi; Number of fractions: 1; Treatment anatomic sites: Regional Site.
   Recorded as not given: adjuvant I-131 Radiation Therapy; adjuvant Pharmaceutical Therapy, NOS.

Follow-up (2 entries)
- Imaging type: CT Scan; Imaging anatomic site: Lymph Node; Timepoint: Preoperative.
- Follow-up contact recording only the day: day 3,296.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-EL-A3D6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 210 mg.
  Slide TCGA-EL-A3D6-01A-01-TS1: Section location: Top; Percent tumor cells: 60; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 40; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 0.
- Sample TCGA-EL-A3D6-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-EL-A3D6-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; History radiation exposure: No; Submitted tumor site: Thyroid; Histologic diagnosis: Thyroid Papillary Carcinoma - Classical/usual; Laterality: Left lobe; Lymph nodes preop imaging: Yes; Lymph nodes examined: Yes; I 131 radiation first treatment method: Patient did not receive I-131 treatment; New tumor event diagnosis indicator: No.
- Neoplasm dimension: Tumor size width: 6.0.
- Lymph node preoperative assessment diagnostic imaging types: Lymph nodes preop imaging type: CT with contrast.
- Follow-up form: Lost to follow-up: Yes.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 3,296 days; disease-specific survival: no event (censored), 3,296 days; progression-free interval: no event (censored), 3,296 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-EL-A3D6-01A-12D-A201-01): tumor purity 0.66, ploidy 2, whole-genome doublings 0.
